Surgical pathology report (de-identified scan), TCGA case TCGA-G3-AAV4, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Alberta Health Services, specimen TCGA-G3-AAV4-01A (Primary Tumor).

[page 1 of 3]
CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected

Time Reported

Order Number

Status

Final

Time Received

Time Transmitted

Ordering Provider

Relevant Information

Location

Copied To

Copy to Request, Insufficient Data for

Report Patient

Name:

Demographics (for

verification purposes)

Date of Birth:

Sex: F

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number

Collected Date/Time

Received Date/Time

Pathologist

Specimen Description

A. Gallbladder at

B. Right hepatectomy at

Clinical Information

Hepatitis B-HCC

Infectious patient: No

Immunocompromised: No

History of neoplasm: No

ICD.O-3
Carcinoma, hepatocellular NOS 8170/3
Site: Liver C22.0
W 5/20/14

Diagnosis

A. Gallbladder, cholecystectomy:

- Gallbladder with no significant pathologic abnormality

B. Liver, right hepatectomy:

- Well-differentiated hepatocellular carcinoma
- Tumor size: 8.0 x 7.2 x 5.8 cm
- Tumor comes within 0.2 cm of resection margin
- Negative for lymphovascular invasion
- Multiple embolized vessels identified; consistent with prior procedure
- Background liver shows moderate portal lymphocytic infiltration (grade 3) and bridging fibrosis (stage 3), consistent with chronic viral hepatitis B
- Please see synoptic report

Reported by:

Electronically signed by:

Verified:

[page 2 of 3]
Responsible Resident:

Synoptic Report

B: Liver, Resection, Microscopic

HISTOLOGIC TYPE:

Hepatocellular carcinoma

HISTOLOGIC GRADE:

GI: Well differentiated

TUMOR EXTENSION (select all that apply):

Tumor confined to liver

PRIMARY TUMOR (pT):

pT1: Solitary tumor with no vascular invasion

REGIONAL LYMPH NODES (pN):

pNX: Cannot be assessed

DISTANT METASTASIS (pM):

pMX: Cannot be assessed

MARGINS:

Parenchymal margin uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 0.2 mm

*VENOUS (LARGE VESSEL) INVASION (V):

*Absent

*ADDITIONAL PATHOLOGIC FINDINGS:

*Hepatitis (specify type): Hepatitis B viral hepatitis

Gross Description

Received are specimen containers A to D. All requisitions and specimen containers are labelled with the patient's name, . The cassettes and identifiers are labelled with the Surgical Number

A. Specimen is received fresh. The container is designated " Gallbladder" and consists of an intact gallbladder, measuring 8.0 x 3.0 x 1.5 cm. The gallbladder has a smooth serosal surface. On opening the gallbladder contains approximately 10.0 ml of dark green bile and no stones. The mucosal surface is homogeneously green with normal appearing architecture. Representative sections are submitted in one cassette.

B. Specimen is received fresh. The container is designated " Right hepatectomy" and consists of a portion of liver, which weighted 347 g in the fresh state and the margin was inked blue. The specimen was tumor banked when received fresh. Following fixation the portion of liver, measures 12.0 x 7.0 x 11.0 cm and has a smooth capsular surface. A circumscribed mass with a yellow tan parenchyma and central area of scarring with hemorrhage is present, measuring 7.2 x 5.8 x 8.0 cm. This tumor comes within 0.2 mm of the liver capsule and within 0.3 cm from the inked margin. The background liver has a yellow coloration and appears fibrotic. Possible emboli are identified in the background liver, but no satellite tumor nodules are present. Representative sections are submitted as follows:

- B1/2. tumor with closest margin
- B3. tumor in relationship to background liver
- B4. tumor in relationship to liver capsule
- B5-9. additional representative sections of tumor
- B10/11. sections showing possible emboli
- B12. representative sections of background liver

Microscopic Description

Immunohistochemistry in the background liver shows focal positivity for hepatitis B core antigen in some nuclei and strong focal positivity for hepatitis B surface antigen, consistent with the patient's history of hepatitis B infection.

[page 3 of 3]
The tumor cells are negative for alpha-feto protein. Negativity for this marker can be seen in hepatocellular carcinomas. The tumor morphology is consistent with hepatocellular carcinoma.

Accession Number
Encounter Number
Patient Location

Source: NCI Genomic Data Commons file 556a9935-63b9-4e13-89d9-45d617179ada (TCGA-G3-AAV4.85CCE331-652C-4D5B-9ED6-ECA8B57AE1AF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).